Somatic mutation profile of tumor specimen TARGET-20-PARZYL-09A (aliquot TARGET-20-PARZYL-09A-01D) from TARGET case TARGET-20-PARZYL, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 17.9 years (6,534 days).
Specimen TARGET-20-PARZYL-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c8bccda7-d31c-4d08-8fec-5402631705ea.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARZYL-14A (Bone Marrow Normal), aliquot TARGET-20-PARZYL-14A-02D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b1f628b-017e-42e3-8f1d-ab2e80b0f105

The open-access MAF lists 12 somatic variants for this specimen: 1 protein-altering or splice-affecting, 3 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 6, Silent 3, 5'UTR 1, 3'Flank 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC168 | c.2222A>T p.K741I | Missense Mutation (SNP) | VAF 111/225 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as rs1481947472; called by muse, mutect2, varscan2
- CCDC168 | c.15792A>G p.K5264= | Silent (SNP) | VAF 109/221 reads (49%) | catalogued as rs768948367; called by muse, mutect2, varscan2
- EP300 | c.2766G>A p.A922= | Silent (SNP) | VAF 37/78 reads (47%) | catalogued as rs370810144; called by muse, mutect2, varscan2
- TMC3 | c.141G>A p.P47= | Silent (SNP) | VAF 57/119 reads (48%) | catalogued as rs375088581; called by muse, mutect2, varscan2
- AC104389.6 | c.*3_*6delinsCTCT | 3'UTR (ONP) | VAF 50/59 reads (85%) | catalogued as rs386750130; called by pindel, varscan2*
- AXIN1 | c.*575_*625delinsGCCAGCAGGGGCTGCCCGAGTCTGTTTTTCATGCGATGACACTTGTAC | 3'UTR (DEL) | VAF 27/96 reads (28%) | called by pindel, varscan2*
- CPM | c.*3131T>C | 3'UTR (SNP) | VAF 56/130 reads (43%) | called by muse, mutect2, varscan2
- DPP6 | c.-258C>T | 5'UTR (SNP) | VAF 50/100 reads (50%) | catalogued as rs1270136127; called by muse, mutect2, varscan2
- EVC | c.*1150A>G | 3'UTR (SNP) | VAF 22/194 reads (11%) | catalogued as rs1195713966, COSV104368962; ClinVar: uncertain significance; called by muse, varscan2
- HCFC2 | c.*3165T>C | 3'UTR (SNP) | VAF 81/164 reads (49%) | catalogued as rs940819934; called by muse, mutect2, varscan2
- PTPN11 | c.*1413A>C | 3'UTR (SNP) | VAF 46/106 reads (43%) | catalogued as rs765490519; called by muse, mutect2, varscan2
- TMPRSS13 | chr11:117901381 G>C | 3'Flank (SNP) | VAF 81/173 reads (47%) | catalogued as rs1047253636; called by muse, mutect2, varscan2
